TCGA case TCGA-N7-A4Y0 — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b0770eff-dff2-4e10-8fc9-c07a81efcc5e

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Dead; Days to death: 771 days (2.1 years).

Diagnoses (2)
1. Mullerian mixed tumor (the primary disease): ICD-O-3 morphology code: 8950/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 65.7 years (23,983 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; FIGO staging edition year: 1988; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 72.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 2; Lymph nodes tested: 6.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 21 days; Days to treatment end: 96 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Ifosfamide; Days to treatment start: 305 days; Days to treatment end: 324 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Mesna; Days to treatment start: 305 days; Days to treatment end: 324 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 607 days (1.7 years); Days to treatment end: 636 days (1.7 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 690 days (1.9 years); Days to treatment end: 690 days (1.9 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Progression of diagnosis 1 (Mullerian mixed tumor), site: Retroperitoneum. Age at diagnosis: 66.4 years (24,264 days); Days to diagnosis: 281 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 281 days; Residual disease: RX.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 281 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Retroperitoneum; Days to progression: 281 days.
- Days to follow up: 771 days (2.1 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 157 cm; BMI: 28.4.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N7-A4Y0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-N7-A4Y0-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 40.
- Sample TCGA-N7-A4Y0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N7-A4Y0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Diabetes diagnosis indicator: Yes; Pregnancies full term count: 2; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Uterus; Histologic diagnosis: Uterine Carcinosarcoma/ MMMT: Heterologous Type; Surgical approach at diagnosis: open; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Pharmaceutical therapy drug name: Mesna.
- Drug treatment 3: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 771 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 771 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 281 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N7-A4Y0-01A-12D-A28Q-01): tumor purity 0.83, ploidy 2.27, whole-genome doublings 0.
